CCDI case PBBJNV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/11cf3654-67f1-4b50-b716-7f3c20b82803

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 11.7 years (4,281 days).

Biospecimens (2 samples)
- Sample 0DA4F0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DA4F2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
